Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8IC, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8IC-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT PELVIC LYMPH NODES:
Twenty one lymph nodes, no tumor present.
(B) LEFT PELVIC LYMPH NODES:
Seventeen lymph nodes, no tumor present.
(C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

ICD O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
gn 11/24/13

GROSS DESCRIPTION

- (A) RIGHT PELVIC LYMPH NODES - Multiple fragments of tan-red soft tissue and fat, measuring 3.0 x 3.0 x 1.5 cm. Lymph nodes are separated and submitted.
SECTION CODE: A1, A2, one lymph node (bisected); A3, A4, one lymph node each; A5, four possible lymph nodes; A6, seven possible lymph nodes; A7, seven possible lymph nodes.
(B) LEFT PELVIC LYMPH NODES - Multiple fragments of tan-red soft tissue, measuring 3.0 x 3.0 x 1.0 cm in aggregate. Lymph nodes are separated and submitted.
SECTION CODE: B1, B2, one lymph node; B3, B4, one lymph node each; B5, five possible lymph node; B6, three possible lymph nodes.
(C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

Prostate cancer

SNOMED CODES

T-C4600, M-00110

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4 + 5). (SEE COMMENT)

TUMOR EXTENDING INTO EXTRAPROSTATIC TISSUE.

TUMOR INVADING RIGHT SEMINAL VESICLE.

MARGINS OF RESECTION, FREE OF TUMOR.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

LYMPHATIC/VASCULAR INVASION PRESENT.

Left seminal vesicle and segment of vasa deferentia, no tumor present.

One periprostatic lymph node, no tumor present.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor is located in the right lateral, right posterolateral, right posterior, mid posterior, left posterior and left posterolateral peripheral zone. The tumor focus measures 3.0 x 1.5 cm in the largest cross-sectional dimension, and it is present in two cross sections and extensively in the apex and base regions. The tumor exhibits extraprostatic extension in the right superior neurovascular bundle region. Extraprostatic extension is present in three sections and the added length of extraprostatic tumor is 8.0 mm. The margins of resection are free of tumor. The tumor invades in the intraprostatic portion of the right seminal vesicle. The margins of resection are free of tumor.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.6 x 3.0 x 3.7 cm, 46 grams, post fixation) has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. A palpable nodule is present in the right base region. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the right peripheral zone of the two cross sections of the prostate. There is a portion of extraprostatic tissue attached to the left side of the prostate. The surface of the fragment which does not represent the true margin is inked blue. Similarly, blue ink is applied to the surface of the prostate in areas under sutures.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: C1-C3, extraprostatic tissue attached to left side of prostate; C4-C6, right seminal vesicles and segment of right vas deferens from the base towards the tip; C7-C11, left seminal vesicle and segment of left vas deferens from the base towards the tip; C12, prostatic base, right border; C13-C17, prostatic base, right posterior border; C18-C25, prostatic base, central portion; C26, prostatic base, left border; C27-C31, prostatic base, left posterior border; C32-C36, apex anterior; C37, C38, apex left; C39-C42, apex posterior; C43-C46, apex right; C47-C48, detached portions of margin of resection according to

[page 3 of 3]
Specimen Date/Time:

specimen radiograph; C49-C57, sections of the two cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (C2, C10, C11, C39-C42) and orange ink (C50-C53, C56 and C57) denote surfaces and do not represent the true margin of resection.

SNOMED CODES

T-92000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 3b026bc1-e4eb-49f4-84bb-d97172b69a77 (TCGA-KK-A8IC.D11CB264-3D9E-49ED-85AA-57E4A26A5ED1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).